MMRF case MMRF_1061 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1ae87b38-ecbe-4e09-92d3-84a2c11f08fd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.3 years (25,691 days); ISS stage: II; Days to last known disease status: 1,808 days (5.0 years); Days to last follow up: 1,808 days (5.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 437 mg/dL; Immunoglobulin G 47.5 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 4.89 µg/mL; Lactate Dehydrogenase 9.04 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 20.8 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 220 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.93 mmol/L; Albumin 45 g/L; Total Protein 10.5 g/dL; Glucose 8.53 mmol/L.
- Day 86: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.9 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 7.01 µg/mL; Lactate Dehydrogenase 10.9 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 520 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.34 mmol/L.
- Day 178 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 6.99 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 111 µmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL.
- Day 274 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Immunoglobulin G 2.37 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 5.21 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.61 mmol/L.
- Day 386 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 5.33 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 5.07 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 6.05 mmol/L.
- Day 470 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 4.68 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 4.54 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 561 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 4.72 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 154 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.95 mmol/L.
- Day 652 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.81 g/L; Beta 2 Microglobulin 4.47 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.29 mmol/L.
- Day 743 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 4.71 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 4.45 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 7.26 mmol/L.
- Day 827 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 141 µmol/L; Calcium 2.38 mmol/L.
- Day 911 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 5.23 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 4.82 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.4 mmol/L.
- Day 1,009 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 8.35 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 1,094 (ECOG 0): Hemoglobin 8.06 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 1,192 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.98 mg/dL; Immunoglobulin G 5.91 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 3.88 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 158 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.45 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 6.38 mmol/L.
- Day 1,276 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.95 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 3.53 µg/mL; Lactate Dehydrogenase 8.62 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 1,382 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.6 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 4.7 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.39 mmol/L.
- Day 1,480 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.5 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 3.79 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 4.4 mmol/L.
- Day 1,571 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 53 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 3.05 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 13 ×10⁹/L; Absolute Neutrophil 8.9 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 4.73 mmol/L.
- Day 1,662 (ECOG 1): Immunoglobulin G 19.5 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 8 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 6.11 mmol/L.
- Day 1,808 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 145 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 21.8 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 301 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 5.7 g/dL; Glucose 8.42 mmol/L.

Other clinical attributes
- Day 1: Weight: 69 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1061_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1061_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1061_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,276 days (3.5 years).
